TARGET case TARGET-40-NAAGJX — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b9f2dcad-c13f-5b37-81c0-1b31fe54862b

Demographics
Sex at birth: male; Race: asian; Age at index: 10 years; Vital status: Dead; Days to death: 1,475 days (4.0 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.0; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 10.1 years (3,700 days); Year of diagnosis: 2010; Metastasis at diagnosis: Metastasis, NOS; Days to last follow up: 1,475 days (4.0 years); Sites of involvement: Lung, NOS.
   Pathology details: Necrosis percent: 80.

Follow-up (2 entries)
- Days to follow up: 454 days (1.2 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 454 days (1.2 years); Days to first event: 454 days (1.2 years); First event: Relapse.
- Days to follow up: 1,475 days (4.0 years); Progression or recurrence: Yes; Progression or recurrence type: Local; Year of follow up: 2014.

Biospecimens (3 samples)
- Sample TARGET-40-NAAGJX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAGJX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TARGET-40-NAAGJX-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAGJX-01A-01D:
- Specimen Type: tumor DNA
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 98
- % Non Tumor Nuclei: Top from Biopsy: 2
- % Cellular Tumor: Top from Biopsy: 95
- % Normal: Top from Biopsy: 0
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 5

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1475
- Protocol: Other osteosarcoma
- Disease at diagnosis: Metastatic
- Metastasis site: Lung only
- Primary tumor site: Arm/hand
- Specific tumor site: Humerus
- Specific tumor region: Proximal
- Definitive Surgery: Limb sparing
- Primary site progression: Yes
- Site of initial relapse: Lung
- Time to first enrollment on relapse protocol in days: 470
